Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7IX, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7IX-01A (Primary Tumor).

Patient:
B-Day:
Patho-No.:

Commentary:

Histology and morphology correspond to anaplastic astrocytoma WHO grade III.

Diagnosis:

Anaplastic astrocytoma WHO grade III

ICD-6-3
Astrocytoma, anaplastic 9401/3
Site Brain, supratentorial NOS
C71.0
9/30/13

Untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file 13ee28d4-2075-412a-83a8-6a200249470b (TCGA-S9-A7IX.BCA5F1A6-7BAB-416F-81A1-C88B83511A2D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).